Somatic mutation profile of tumor specimen MMRF_1020_3_BM_CD138pos (aliquot MMRF_1020_3_BM_CD138pos_T1_KBS5U_L06452) from MMRF case MMRF_1020, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,143 days).
Specimen MMRF_1020_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b08162f0-232b-453e-8e03-755d525f1a61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1020_3_PB_Whole (Blood Derived Normal), aliquot MMRF_1020_3_PB_Whole_C2_KBS5U_L06484; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40999633-7157-4a4e-b294-e49240a3cf44

The open-access MAF lists 223 somatic variants for this specimen: 85 protein-altering or splice-affecting, 22 silent, 116 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 58, Intron 38, Silent 22, Nonsense Mutation 7, 5'UTR 6, 5'Flank 5, RNA 5, 3'Flank 4, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AFM | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs765491382; called by muse, mutect2, varscan2
- AMPH | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs939391412; called by muse, mutect2, varscan2
- ATP10B | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as rs1157520743, COSV104402027; called by muse, mutect2, varscan2
- C6orf132 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as rs1015415208; called by muse, mutect2, varscan2
- CACNA1E | c.6853C>T p.R2285W (on ENST00000367573 / NM_001205293.3; = p.R2242W on NM_000721.4) | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs769784112, COSV62385937; called by muse, mutect2, varscan2
- COQ8B | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54574079; called by muse, mutect2, varscan2
- CRLF2 | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV67494129, COSV67494448; called by muse, mutect2, varscan2
- CUL3 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52369738; called by muse, mutect2, varscan2
- EPHB1 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67666566; called by muse, mutect2, varscan2
- ERCC6 | c.3586C>G p.L1196V | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs369489725; called by muse, mutect2, varscan2
- FAM189A2 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369333590; called by mutect2, varscan2
- FASN | c.1925G>A p.C642Y | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60751960; called by muse, mutect2, varscan2
- IGKJ4 | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 36/38 reads (95%) | PolyPhen benign (0.034); catalogued as rs139461207; called by muse, varscan2
- ITGA11 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs762389646; called by muse, mutect2, varscan2
- LIG3 | c.1597G>C p.V533L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV52005837; called by muse, mutect2, varscan2
- MORC3 | c.2393G>A p.S798N | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs796950649; called by muse, mutect2, varscan2
- MYOZ2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.085); catalogued as COSV100201645; called by muse, mutect2, varscan2
- PCDH15 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57302701, COSV57365197; called by muse, mutect2
- PNLIP | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371065609; called by muse, mutect2, varscan2
- PRR29 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1445976139; called by muse, mutect2, varscan2
- RND1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV59045263; called by muse, mutect2
- RPL11 | c.278T>G p.L93* (on ENST00000374550 / NM_001199802.1; = p.L94* on NM_000975.5) | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as CM122320; called by muse, varscan2
- RPL11 | c.377G>A p.G126D (on ENST00000374550 / NM_001199802.1; = p.G127D on NM_000975.5) | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV65778567; called by muse, varscan2
- SCART1 | c.2710G>A p.V904M | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1185077124; called by muse, mutect2, varscan2
- TOB1 | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs1436370305; called by muse, mutect2, varscan2
- WDFY4 | c.4855T>C p.F1619L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs1400894459; called by muse, mutect2, varscan2
- XRN1 | c.4973C>T p.P1658L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as rs764602779; called by muse, mutect2, varscan2
- ZDBF2 | c.4339T>A p.C1447S | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV65629747; called by muse, mutect2, varscan2
- ZNF260 | c.898G>T p.G300* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | catalogued as rs753221805; called by muse, mutect2, varscan2
- ABCA13 | c.12228+2T>A p.X4076_splice | Splice Site (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- ALDH3B1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANGEL1 | c.1689-6C>A | Splice Region (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- CARHSP1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH26 | c.1250dup p.P418Tfs*3 | Frame Shift Ins (INS) | VAF 119/240 reads (50%) | called by mutect2, pindel, varscan2
- CLGN | c.1648A>G p.K550E | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COG1 | c.560+1G>T p.X187_splice | Splice Site (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- CORO1C | c.48A>C p.Q16H | Missense Mutation (SNP) | VAF 31/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CPN1 | c.844G>T p.G282W | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRTC1 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK5 | c.3727T>C p.Y1243H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- EPS8L2 | c.1730dup p.S578Kfs*193 | Frame Shift Ins (INS) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- FAT1 | c.2217G>A p.M739I | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBH1 | c.2773G>A p.A925T (on ENST00000362091 / NM_178150.3; = p.A976T on NM_032807.4) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FCRLB | c.371G>C p.C124S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FMN1 | c.3377+8T>C | Splice Region (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- GAB4 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- GBX2 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GMCL2 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- GPRIN2 | c.1015G>C p.A339P | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ICE1 | c.3259del p.Q1087Kfs*23 | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | called by pindel, varscan2
- ITPR1 | c.5743C>T p.Q1915* (on ENST00000354582; = p.Q1860* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1567A>G p.K523E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- MDN1 | c.2084G>A p.G695D | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MTRES1 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NCKAP5 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NEBL | c.518A>T p.Y173F | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NEFH | c.1172T>G p.V391G | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFX1 | c.1099G>C p.V367L | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOD2 | c.2999C>G p.A1000G | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- NUS1 | c.433A>T p.N145Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PLCB2 | c.3513G>C p.Q1171H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PLCE1 | c.5168G>C p.S1723T | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PNPLA8 | c.1241A>G p.Q414R | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PPP1R37 | c.78del p.S27Lfs*45 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | called by mutect2, pindel, varscan2
- RILPL1 | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RUSC2 | c.3791G>T p.R1264L | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SCN2A | c.4092C>G p.Y1364* | Nonsense Mutation (SNP) | VAF 59/110 reads (54%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.826A>C p.K276Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2
- SNCG | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SNX22 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SULF1 | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- SYBU | c.1204A>G p.T402A (on ENST00000276646 / NM_001099754.2; = p.T401A on NM_017786.6) | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, varscan2
- SYNC | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SYNPO2L | c.962C>T p.A321V (on ENST00000394810 / NM_001114133.3; = p.A97V on NM_024875.5) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- THG1L | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.39701A>G p.E13234G (on ENST00000591111; = p.E5810G on NM_003319.4) | Missense Mutation (SNP) | VAF 28/117 reads (24%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBA7 | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- USP29 | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSTM1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WRN | c.858G>C p.K286N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZBTB7C | c.1024C>G p.H342D | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZGRF1 | c.4332_4364del p.K1445_E1455del | In Frame Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel
- ZMIZ2 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF735 | c.816A>C p.E272D | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- ACVR2A | c.705C>G p.V235= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- BNIPL | c.72A>T p.L24= | Silent (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- CARD10 | c.537G>A p.Q179= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- DACT2 | c.840C>T p.H280= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs569420736; called by muse, mutect2, varscan2
- DMBT1 | c.7398T>C p.L2466= (on ENST00000338354 / NM_001377530.1; = p.L1709= on NM_004406.3) | Silent (SNP) | VAF 93/173 reads (54%) | called by muse, mutect2, varscan2
- GLDC | c.1350G>A p.L450= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, varscan2
- GPR162 | c.678A>G p.K226= | Silent (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- JMJD1C | c.4194A>T p.V1398= | Silent (SNP) | VAF 98/211 reads (46%) | called by muse, mutect2, varscan2
- KIF13B | c.3312G>A p.E1104= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as rs780947624; called by muse, mutect2, varscan2
- LTB | c.136T>C p.L46= | Silent (SNP) | VAF 50/110 reads (45%) | called by muse, varscan2
- MPG | c.651C>T p.G217= | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- OR2A2 | c.588G>A p.V196= | Silent (SNP) | VAF 78/160 reads (49%) | called by muse, mutect2, varscan2
- OR8B8 | c.105C>T p.Y35= | Silent (SNP) | VAF 78/165 reads (47%) | catalogued as rs140268238, COSV60144530; called by muse, mutect2, varscan2
- PSORS1C1 | c.51G>A p.Q17= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as COSV52535023; called by muse, mutect2, varscan2
- RAI1 | c.240A>T p.R80= | Silent (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- RASGEF1B | c.129G>C p.L43= | Silent (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- SELENOH | c.327G>A p.E109= | Silent (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- SEMG1 | c.39C>G p.L13= | Silent (SNP) | VAF 70/302 reads (23%) | called by muse, mutect2, varscan2
- SF3B3 | c.3579C>G p.V1193= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- SLC5A10 | c.780C>T p.D260= | Silent (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- TLN2 | c.4731C>T p.F1577= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs375986590; called by muse, mutect2, varscan2
- TRABD2A | c.1227C>T p.A409= (on ENST00000409520 / NM_001277053.2; = p.A360= on NM_001080824.3) | Silent (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- ABCA12 | c.164-11438del | Intron (DEL) | VAF 75/185 reads (41%) | called by mutect2, pindel, varscan2
- ABI2 | c.*10879G>A | 3'UTR (SNP) | VAF 49/220 reads (22%) | called by muse, mutect2, varscan2
- AC079612.1 | n.281A>G | RNA (SNP) | VAF 90/144 reads (63%) | called by muse, varscan2
- ACTRT2 | c.*60T>G | 3'UTR (SNP) | VAF 57/116 reads (49%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.2575+643C>T | Intron (SNP) | VAF 21/100 reads (21%) | catalogued as COSV66864414; called by mutect2, varscan2
- ADM2 | c.*1684G>A | 3'UTR (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- AKNAD1 | c.2167+223G>C | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- ALKBH8 | chr11:107565714 C>T | 5'Flank (SNP) | VAF 16/229 reads (7%) | catalogued as rs1347417276; called by muse, mutect2
- ANTXR1 | c.951+10447T>G | Intron (SNP) | VAF 114/205 reads (56%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*3685G>A | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- ARID4B | c.*481A>G | 3'UTR (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- ATP5MPL | c.124+78A>T | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- BMI1 | c.*1539T>A | 3'UTR (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- BMP6 | c.*445G>C | 3'UTR (SNP) | VAF 68/161 reads (42%) | called by muse, mutect2, varscan2
- BX537318.2 | n.541T>C | RNA (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- CACNB4 | c.*3861G>T | 3'UTR (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- CALM2 | chr2:47176575 T>A | 5'Flank (SNP) | VAF 21/110 reads (19%) | catalogued as rs1036919163; called by muse, mutect2, varscan2
- CBY2 | c.156+547G>A | Intron (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- CCDC144A | c.*19C>A | 3'UTR (SNP) | VAF 15/203 reads (7%) | called by muse, mutect2
- CHST10 | c.-104+488del | Intron (DEL) | VAF 83/189 reads (44%) | called by mutect2, pindel, varscan2
- CIT | c.3466-49T>C | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- CLN5 | c.340-38G>A | Intron (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- CMTR2 | c.*234T>C | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- COQ7 | c.*882G>C | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- CPLX1 | c.*1164T>C | 3'UTR (SNP) | VAF 32/158 reads (20%) | catalogued as rs922175049; called by muse, mutect2, varscan2
- CRELD2 | c.869-65A>C | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- CUL4A | chr13:113208489 A>G | 5'Flank (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- CYP7B1 | c.*27C>A | 3'UTR (SNP) | VAF 56/112 reads (50%) | catalogued as COSV100042019, COSV100042173; called by muse, mutect2, varscan2
- DCLK3 | c.*1031A>C | 3'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- DDX31 | c.*384T>G | 3'UTR (SNP) | VAF 53/135 reads (39%) | called by muse, mutect2, varscan2
- DENND5A | c.1907-63G>C | Intron (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- DGKB | c.*3947T>C | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- DSG3 | c.*1138A>G | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- EIF4A2 | c.209-14C>T | Intron (SNP) | VAF 99/176 reads (56%) | called by muse, mutect2, varscan2
- EMP1 | c.*1135C>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | catalogued as rs901060350; called by muse, mutect2, varscan2
- FAM205BP | n.951T>A | RNA (SNP) | VAF 103/461 reads (22%) | called by muse, mutect2, varscan2
- FKTN | c.*4898A>T | 3'UTR (SNP) | VAF 69/245 reads (28%) | called by muse, mutect2, varscan2
- FOXL2NB | c.*836C>T | 3'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- FOXR2 | c.*475C>G | 3'UTR (SNP) | VAF 53/55 reads (96%) | called by muse, mutect2, varscan2
- GAPT | c.*187C>G | 3'UTR (SNP) | VAF 58/228 reads (25%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1161+39A>T | Intron (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- GTPBP10 | c.*5366C>T | 3'UTR (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2
- HLA-C | c.344-18C>T | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as rs775100829; called by muse, mutect2, varscan2
- HOXB3 | c.-159+973G>A | Intron (SNP) | VAF 17/36 reads (47%) | catalogued as rs1483093842; called by muse, mutect2, varscan2
- HOXB4 | c.*419C>T | 3'UTR (SNP) | VAF 39/73 reads (53%) | catalogued as rs1430590333; called by muse, mutect2, varscan2
- HYAL2 | c.-46-471G>C | Intron (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- IFFO2 | c.*1662G>A | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- IFRD2 | c.1440+14G>C | Intron (SNP) | VAF 34/137 reads (25%) | catalogued as rs782526934; called by muse, mutect2, varscan2
- ITGAX | c.*715C>T | 3'UTR (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1733-201C>T | Intron (SNP) | VAF 16/29 reads (55%) | catalogued as rs1464125141; called by muse, mutect2, varscan2
- KIAA1958 | c.*1424A>C | 3'UTR (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- LINC02453 | n.1449A>G | RNA (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- MANEA | c.*2122G>T | 3'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- MINDY2 | c.*4073C>G | 3'UTR (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- MIR5195 | n.103A>T | RNA (SNP) | VAF 39/39 reads (100%) | called by muse, varscan2
- MIR5195 | chr14:106851157 T>C | 5'Flank (SNP) | VAF 131/134 reads (98%) | catalogued as rs556962000; called by muse, mutect2, varscan2
- MMP1 | c.*80C>T | 3'UTR (SNP) | VAF 47/121 reads (39%) | called by muse, mutect2, varscan2
- MYO1C | c.1798-26A>G | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- NDUFV1 | c.511-120del | Intron (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- NEK10 | chr3:27110500 del TTGA | 3'Flank (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- NETO1 | c.-154C>T | 5'UTR (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- NFATC2IP | c.*72G>A | 3'UTR (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- NLK | c.*917A>G | 3'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- NUDT22 | c.481-141_481-137dup | Intron (INS) | VAF 68/180 reads (38%) | called by mutect2, varscan2
- OSTF1 | c.*343G>A | 3'UTR (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- PANK3 | c.*8228T>C | 3'UTR (SNP) | VAF 51/155 reads (33%) | called by muse, mutect2, varscan2
- PCDH11X | c.*2334G>A | 3'UTR (SNP) | VAF 104/118 reads (88%) | called by muse, mutect2, varscan2
- PCNX2 | c.-63G>C | 5'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- PDLIM4 | c.*684C>T | 3'UTR (SNP) | VAF 17/227 reads (7%) | called by muse, mutect2
- PM20D1 | c.*351A>T | 3'UTR (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- PPAN | c.189+58C>A | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- PPP2CA | c.*1902C>G | 3'UTR (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- PTPRT | c.*4909A>G | 3'UTR (SNP) | VAF 97/152 reads (64%) | catalogued as rs544401186; called by muse, mutect2, varscan2
- RAB3C | c.*3043G>A | 3'UTR (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2, varscan2
- RARRES2 | c.-21+306C>T | Intron (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- RCC2 | chr1:17408336 G>A | 3'Flank (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- RCSD1 | chr1:167630130 T>A | 5'Flank (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- RNF216 | c.874-259T>A | Intron (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- RNF222 | c.*1498A>G | 3'UTR (SNP) | VAF 19/56 reads (34%) | catalogued as rs759686557; called by muse, mutect2, varscan2
- ROBO2 | c.*201C>T | 3'UTR (SNP) | VAF 31/46 reads (67%) | called by muse, mutect2, varscan2
- ROPN1B | c.*62C>T | 3'UTR (SNP) | VAF 130/287 reads (45%) | called by muse, mutect2, varscan2
- SBDS | c.*333C>T | 3'UTR (SNP) | VAF 144/283 reads (51%) | called by muse, mutect2, varscan2
- SCARA5 | c.*1804G>A | 3'UTR (SNP) | VAF 21/44 reads (48%) | catalogued as rs1403787416; called by muse, mutect2, varscan2
- SCNN1G | c.*396G>T | 3'UTR (SNP) | VAF 53/114 reads (46%) | catalogued as COSV55602818; called by muse, mutect2, varscan2
- SELENOS | c.76+181G>C | Intron (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- SETMAR | c.156+122G>A | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as rs777287432, COSV62780863; called by muse, mutect2, varscan2
- SH3GLB2 | chr9:129007661 C>T | 3'Flank (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- SLC12A7 | c.*269G>A | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- SLC22A31 | c.-81G>A | 5'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- SLC25A40 | c.742-199G>A | Intron (SNP) | VAF 62/215 reads (29%) | called by muse, mutect2, varscan2
- SMARCB1 | c.-9G>C | 5'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- SOX1 | c.*747A>G | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- SPG7 | c.1643-106G>A | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- SPON1 | c.-68G>A | 5'UTR (SNP) | VAF 3/10 reads (30%) | catalogued as rs1182138027; called by muse, mutect2
- SPTLC1 | c.*412G>C | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ST3GAL3 | c.211+9368G>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- SUPT7L | c.*1303T>G | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- SUV39H2 | c.849+617T>A | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- TEF | c.*3084A>G | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- TGFBRAP1 | chr2:105266560 G>C | 3'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- THBS2 | c.694+19A>C | Intron (SNP) | VAF 116/238 reads (49%) | called by muse, mutect2, varscan2
- TLL1 | c.*416C>G | 3'UTR (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.-20C>A | 5'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- TRIM17 | c.-5-443G>T | Intron (SNP) | VAF 49/338 reads (14%) | called by muse, mutect2, varscan2
- TRIM67 | c.*217T>G | 3'UTR (SNP) | VAF 113/179 reads (63%) | called by muse, mutect2, varscan2
- TRPM1 | c.1197+17dup | Intron (INS) | VAF 49/107 reads (46%) | catalogued as rs769825661; called by mutect2, varscan2
- UBE3B | c.713+1001G>A | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- UBR4 | c.11892+47C>G | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- USP28 | c.*342G>A | 3'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- USP46 | c.*1335A>T | 3'UTR (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- VPS13A | c.9189+369G>C | Intron (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- ZBTB48 | c.1138-95G>A | Intron (SNP) | VAF 30/129 reads (23%) | catalogued as rs548584176; called by muse, mutect2, varscan2
- ZDHHC13 | c.*237A>G | 3'UTR (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2, varscan2
- ZNF33A | c.*2928C>A | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- ZNF662 | c.*927T>G | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+4176G>T | Intron (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
